Somatic mutation profile of tumor specimen MP2PRT-PAUSNU-TBP1-B (aliquot MP2PRT-PAUSNU-TBP1-B-1-0-D-A83P-36) from MP2PRT case MP2PRT-PAUSNU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.0 years (1,449 days).
Specimen MP2PRT-PAUSNU-TBP1-B: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c3dc1954-5708-41e4-860a-0b8dd1e5a8fe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUSNU-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUSNU-NB1-A-1-0-D-A81Z-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fbf749ed-a56e-49bd-a246-c5c55c5fea0a

The open-access MAF lists 12 somatic variants for this specimen: 11 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 11, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CLU | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 120/588 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1172593465, COSV57067559; called by muse, mutect2, varscan2
- COL7A1 | c.1346G>A p.R449Q | Missense Mutation (SNP) | VAF 119/445 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as rs764504901, COSV60404100; called by muse, mutect2, varscan2
- DMD | c.347T>G p.L116R | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM098339; called by muse, mutect2, varscan2
- GOLGA6L22 | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 122/421 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.225); catalogued as rs1459454497; called by muse, mutect2, varscan2
- MYO5B | c.2990C>T p.S997L | Missense Mutation (SNP) | VAF 171/477 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs749172925; called by muse, mutect2, varscan2
- SPTBN2 | c.1241G>A p.R414H | Missense Mutation (SNP) | VAF 60/760 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as rs903948525; called by muse, mutect2
- TJP1 | c.3250G>A p.V1084I | Missense Mutation (SNP) | VAF 156/384 reads (41%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.001); catalogued as rs367857013; called by muse, mutect2, varscan2
- TSPYL6 | c.665C>A p.A222E | Missense Mutation (SNP) | VAF 204/563 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.308); catalogued as rs373884672; called by muse, mutect2, varscan2
- CFH | c.1492G>A p.G498R | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ECH1 | c.297C>G p.D99E | Missense Mutation (SNP) | VAF 45/334 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- ZNF142 | c.5291C>A p.A1764D (on ENST00000411696 / NM_001379660.1; = p.A1564D on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/631 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.019); called by muse, mutect2
- SHANK2 | c.3150C>A p.G1050= | Silent (SNP) | VAF 152/712 reads (21%) | called by muse, mutect2, varscan2
